Somatic mutation profile of tumor specimen TCGA-18-3407-01A (aliquot TCGA-18-3407-01A-01D-0983-08) from TCGA case TCGA-18-3407, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 72.9 years (26,615 days).
Specimen TCGA-18-3407-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33998825-eaef-46f7-81e8-6e6975f7dd05.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-18-3407-11A (Solid Tissue Normal), aliquot TCGA-18-3407-11A-01D-0983-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71af5b93-09eb-4c85-8492-721bf2049dbf

The open-access MAF lists 72 somatic variants for this specimen: 52 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 19, Frame Shift Del 3, Nonsense Mutation 3, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.329G>A p.W110* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | hotspot (GDC flag); catalogued as rs1057519852, COSV58682976, COSV58690849; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KEAP1 | c.463G>T p.V155F | Missense Mutation (SNP) | VAF 28/85 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV50296596, COSV99408076; called by muse, mutect2, varscan2
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 19/47 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.635_636del p.F212Sfs*3 | Frame Shift Del (DEL) | VAF 11/43 reads (26%) | catalogued as rs864309495; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ASH1L | c.7670T>C p.I2557T (on ENST00000368346 / NM_001366177.2; = p.I2552T on NM_018489.3) | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as COSV64210323; called by muse, mutect2
- ASXL3 | c.4472T>C p.V1491A | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.024); catalogued as rs1433410697, COSV52471705; called by mutect2, varscan2
- B3GNT8 | c.653C>G p.P218R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.546); catalogued as COSV54198349; called by muse, mutect2
- BAIAP3 | c.240A>C p.K80N | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV60981745; called by muse, mutect2
- CACNA1E | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1172205004, COSV62386234; called by mutect2, varscan2
- CCDC40 | c.1456G>A p.D486N | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as rs375800869; called by muse, mutect2, varscan2
- CD1A | c.362T>G p.L121R | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV56862899; called by muse, mutect2, varscan2
- CSMD2 | c.6706A>G p.I2236V | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as rs1359228096, COSV53930892; called by muse, mutect2, varscan2
- CYP2A6 | c.851C>T p.T284M | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); catalogued as rs201027514, COSV56536058; called by mutect2, varscan2
- FTO | c.1193A>T p.Q398L | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV67112808; called by muse, mutect2, varscan2
- HCFC2 | c.1283G>C p.S428T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as COSV57558543, COSV57559097; called by muse, mutect2, varscan2
- HIVEP1 | c.8077C>G p.L2693V | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.474); catalogued as rs773414935, COSV65103195; called by muse, mutect2, varscan2
- HMGB2 | c.39G>T p.M13I | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV56633917; called by muse, mutect2, varscan2
- HSPG2 | c.12405C>A p.F4135L | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV60828820, COSV60828849; called by muse, mutect2, varscan2
- HTR1E | c.223G>A p.V75I | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781747051, COSV59507211; called by mutect2, varscan2
- IQSEC2 | c.2035C>T p.R679W (on ENST00000642864 / NM_001111125.3; = p.R474W on NM_015075.2) | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV64726664; called by muse, mutect2, varscan2
- KIF7 | c.3988C>T p.R1330* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as rs370123540; called by mutect2, varscan2
- KRT73 | c.1184A>C p.K395T | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59840194; called by mutect2, varscan2
- LRP4 | c.4144C>T p.P1382S | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as rs765240067, COSV66137009; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MROH2B | c.943A>C p.M315L | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68186464; called by muse, mutect2, varscan2
- MYH11 | c.891T>C p.S297= | Splice Region (SNP) | VAF 11/71 reads (15%) | catalogued as COSV55559887; called by muse, mutect2, varscan2
- NELL1 | c.1966G>C p.V656L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs751604045, COSV54288346; called by muse, mutect2, varscan2
- ONECUT1 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV59949687; called by mutect2, varscan2
- OR12D2 | c.173A>T p.Y58F | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV65828939; called by muse, mutect2
- PIM3 | c.662A>G p.Y221C | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62260005; called by muse, mutect2, varscan2
- PLD3 | c.80A>T p.E27V | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.034); catalogued as COSV62925220; called by muse, mutect2, varscan2
- PLXNB3 | c.2163G>T p.W721C | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.662); catalogued as COSV62799286; called by muse, varscan2
- PPP1R3A | c.2149G>A p.A717T | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as COSV52886480; called by muse, mutect2, varscan2
- PRKD1 | c.475T>C p.F159L | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59576110; called by muse, mutect2, varscan2
- PSG2 | c.857T>A p.L286Q | Missense Mutation (SNP) | VAF 22/289 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61545776; called by muse, mutect2
- RALGAPA2 | c.3845C>T p.A1282V | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs753953433, COSV52503023; called by mutect2, varscan2
- SEC14L1 | c.1850G>A p.G617E | Missense Mutation (SNP) | VAF 43/234 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66723374; called by muse, mutect2, varscan2
- SIN3B | c.734G>C p.G245A | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.08); catalogued as COSV56134558; called by muse, mutect2, varscan2
- SSTR2 | c.901A>T p.T301S | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59535671; called by muse, mutect2, varscan2
- TAP1 | c.1148G>C p.G383A | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.96); PolyPhen benign (0.006); catalogued as COSV62755050; called by muse, mutect2
- TMEM135 | c.700T>A p.C234S | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.675); catalogued as COSV59701354, COSV59702803; called by muse, mutect2, varscan2
- TMPO | c.654T>G p.F218L | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.087); catalogued as COSV99702061; called by muse, mutect2, varscan2
- TRPA1 | c.2051C>T p.T684I | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV51566605; called by mutect2, varscan2
- TRPM8 | c.2108C>A p.P703H | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61222746; called by muse, mutect2, varscan2
- TTLL12 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV53355968; called by muse, mutect2, varscan2
- USP37 | c.2522T>G p.L841R | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51445003; called by muse, mutect2
- VIL1 | c.1128T>A p.D376E | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV50291122; called by mutect2, varscan2
- VSTM1 | c.506C>A p.S169Y | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as rs749666791, COSV100618820, COSV58075639; called by muse, mutect2, varscan2
- ZFHX4 | c.2099G>A p.R700H | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781379151, COSV51466756, COSV99268536; called by mutect2, varscan2
- ZNF493 | c.148G>T p.G50* | Nonsense Mutation (SNP) | VAF 17/42 reads (40%) | catalogued as COSV62750856; called by muse, mutect2, varscan2
- ZNF831 | c.4828A>T p.S1610C | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); catalogued as COSV64037923, COSV64042404; called by muse, mutect2, varscan2
- DSG3 | c.1720_1735del p.N574Hfs*4 | Frame Shift Del (DEL) | VAF 29/226 reads (13%) | called by mutect2, pindel
- FAM135B | c.1701del p.E567Dfs*21 | Frame Shift Del (DEL) | VAF 10/88 reads (11%) | called by mutect2, varscan2
- CKAP2L | c.1938G>C p.T646= | Silent (SNP) | VAF 36/191 reads (19%) | catalogued as COSV56697046; called by muse, mutect2, varscan2
- DHRS9 | c.39T>G p.G13= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV100513550; called by muse, mutect2
- DHX29 | c.4011T>C p.D1337= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV52419445; called by muse, mutect2, varscan2
- DLG4 | c.2124C>T p.I708= (on ENST00000399506 / NM_001321075.3; = p.I751= on NM_001365.4) | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as rs768829657, COSV57240074; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.840C>T p.T280= | Silent (SNP) | VAF 14/192 reads (7%) | catalogued as COSV62568860; called by muse, mutect2
- KAT5 | c.297G>A p.A99= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs773998223, COSV57730161; called by mutect2, varscan2
- KDM3A | c.2229G>A p.A743= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs546755224, COSV57223190; called by muse, mutect2, varscan2
- PCDHB16 | c.2202G>A p.G734= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as COSV53365900; called by muse, mutect2, varscan2
- PCOLCE | c.1029G>A p.V343= | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as rs1377964861, COSV56158488; called by muse, mutect2, varscan2
- PCSK6 | c.1044C>T p.G348= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs755571481, COSV59342555; called by mutect2, varscan2
- PKDREJ | c.6420A>G p.E2140= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV53550677; called by muse, mutect2, varscan2
- RFTN2 | c.570A>T p.S190= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV54390489; called by muse, mutect2, varscan2
- SAFB | c.378C>T p.I126= | Silent (SNP) | VAF 15/130 reads (12%) | catalogued as rs764882015, COSV52652475; called by mutect2, varscan2
- SCN7A | c.966T>C p.C322= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV69272909; called by muse, varscan2
- SNTB1 | c.912G>A p.V304= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV67327600; called by muse, mutect2, varscan2
- SPATA31D1 | c.1461A>G p.P487= | Silent (SNP) | VAF 19/119 reads (16%) | catalogued as COSV61198192; called by muse, mutect2, varscan2
- TNC | c.5586A>G p.E1862= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as COSV60786962; called by muse, mutect2, varscan2
- TOM1L1 | c.663C>T p.A221= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs141567240; called by mutect2, varscan2
- ZAN | c.5922C>T p.A1974= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV61811516; called by muse, mutect2, varscan2
- SNORD115-15 | n.61A>C | RNA (SNP) | VAF 36/417 reads (9%) | called by muse, mutect2
